FM case AD7693 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Thymic Epithelial Neoplasms; Primary site: Thymus.
https://portal.gdc.cancer.gov/cases/81b2f404-8efd-46c3-84ca-c3c94aa29b8b

Male, 67.5 years: Thymoma, NOS (ICD-O-3 8580/1) of the thymus; metastasis biopsied or resected from the mediastinum. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
